Surgical pathology report (de-identified scan), TCGA case TCGA-61-2096, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2096-01A (Primary Tumor).

DIAGNOSIS:

1: SMALL BOWEL MESENTERY, BIOPSY –
FIBROADIPOSE TISSUE WITH CHRONIC INFLAMMATION AND MESOTHELIAL PROLIFERATION.

PART 2: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY –

- A. MODERATELY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF RIGHT OVARY.
- B. UNREMARKABLE RIGHT FALLOPIAN TUBE.

PART 3: POSTERIOR CUL-DE-SAC, BIOPSY –

REACTIVE FIBROUS TISSUE WITH ACUTE AND CHRONIC INFLAMMATION, MESOTHELIAL PROLIFERATION AND FOCAL ENDOSALPINGIOSIS.

PART 4: LEFT CUL-DE-SAC NODULE, BIOPSY –

REACTIVE FIBROUS TISSUE WITH ACUTE AND CHRONIC INFLAMMATION AND MESOTHELIAL PROLIFERATION.

PART 5: UTERUS (76 grams) AND LEFT ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND LEFT SALPINGO-OOPHORECTOMY –

- A. CHRONIC CERVICITIS, SQUAMOUS METAPLASIA AND ENDOCERVICAL TUNNEL CLUSTERS.
- B. INACTIVE ENDOMETRIUM.
- C. UNREMARKABLE MYOMETRIUM.
- D. LEFT OVARY WITH PHYSIOLOGIC CHANGES.
- E. LEFT FALLOPIAN TUBE, UNREMARKABLE.

PART 6: LEFT COMMON ILIAC LYMPH NODES, DISSECTION –
ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

PART 7: LEFT EXTERNAL ILIAC LYMPH NODES, DISSECTION –
FIBROADIPOSE TISSUE, NO LYMPH NODES IDENTIFIED.

PART 8: EXTERNAL/INTERNAL ILIAC LYMPH NODES, DISSECTION –
FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).

PART 9: LEFT OBTURATOR LYMPH NODES, DISSECTION –
ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

PART 10: RIGHT COMMON DUCT, BIOPSY –
TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2).

PART 11: RIGHT EXTERNAL/INTERNAL LYMPH NODES, DISSECTION –
SEVEN LYMPH NODES, NEGATIVE FOR TUMOR (0/7).

PART 12: RIGHT OBTURATOR LYMPH NODES, DISSECTION –
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 13: ANTERIOR CUL-DE-SAC PERITONEUM, BIOPSY –
FIBROADIPOSE TISSUE WITH MESOTHELIAL PROLIFERATION.

PART 14: RIGHT PELVIC SIDEWALL, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 15: LEFT PELVIC SIDEWALL, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 16: LEFT GUTTER, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 17: RIGHT GUTTER, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 18: LEFT PERIAORTIC LYMPH NODES, BIOPSY –
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 19: RIGHT PERIAORTIC LYMPH NODES, BIOPSY –
THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 20: OMENTUM, OMENTECTOMY –
NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file 9c1e9f32-54a0-459f-9f83-4ede5fb67f49 (TCGA-61-2096.9F95FE7D-4865-4CA5-BB57-9D47C388A7ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).